Gene-level copy-number profile of tumor specimen TCGA-23-1124-01A from TCGA case TCGA-23-1124, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 63.0 years (23,005 days).
Specimen TCGA-23-1124-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.5fc24346-0d8a-4f26-9b42-f52d5fbd94e4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-23-1124-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b49de879-74bb-4edf-9f86-5fc4ec29f0da

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 3,322; copy number 2: 14,718; copy number 3: 17,350; copy number 4: 14,669; copy number 5: 5,606; copy number 6: 2,848; copy number 7: 844; copy number 8: 273; copy number 9: 112; copy number 10: 73.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-23-1124-01A-01D-0428-01): tumor purity 0.76, ploidy 3.28, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,302 genes in 23 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:29,192,657–33,200,353, 113 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr1:33,261,212–33,261,680, 1 gene, copy number 7: AL513327.2.
- chr1:200,478,020–203,508,949, 104 genes, copy number 7 (broad region; genes not listed).
- chr1:238,107,736–238,108,567, 1 gene, copy number 8: YWHAQP9.
- chr2:46,256,860–47,387,601, 34 genes, copy number 9 (within-gene range 6–9): RPL36AP14, Metazoa_SRP, EPAS1, LINC01820, LINC02583, AC016912.2, AC016912.1, RN7SL817P, TMEM247, ATP6V1E2, RHOQ, RHOQ-AS1, PIGF, CRIPT, AC020604.1, LINC01118, SOCS5, LINC01119, AC016722.1, AC016722.2, MCFD2, TTC7A, AC093732.2, AC093732.1, STPG4, AC073283.3, AC073283.1, CALM2, EPCAM-DT, AC073283.2, BCYRN1, EPCAM, RN7SKP119, MIR559.
- chr2:48,809,340–55,112,621, 62 genes, copy number 8 (broad region; genes not listed).
- chr2:59,218,680–60,100,200, 1 gene, copy number 7 (within-gene range 5–7): AC007100.1.
- chr2:59,647,621–66,573,869, 151 genes, copy number 7 (broad region; genes not listed).
- chr3:102,099,244–102,479,841, 1 gene, copy number 7 (within-gene range 5–7): ZPLD1.
- chr3:149,433,044–150,343,210, 30 genes, copy number 7: AC108751.2, AC108751.3, FKBP1AP4, AC108751.1, TM4SF4, AC108751.5, WWTR1, RNU6-1098P, WWTR1-IT1, WWTR1-AS1, COMMD2, ANKUB1, RNU6-507P, RNF13, RNU6-720P, NPM1P29, PFN2, AC117395.1, TMEM183B, PPIAP73, HNRNPA1P24, AC117386.2, AC022494.1, LINC01998, RPL32P9, AC117386.1, LINC01213, U2, LINC01214, AC018545.1.
- chr3:153,384,934–157,174,040, 70 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr3:157,230,320–157,235,149, 2 genes, copy number 7: AC092944.2, AC092944.3.
- chr5:58,198–612,210, 24 genes, copy number 8: AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1.
- chr6:73,593,379–79,081,371, 54 genes, copy number 8: SLC17A5, RPS27P15, AL590428.1, CD109, AL590552.1, TXNP7, AL357507.1, AL357563.1, AL356277.3, AL356277.1, AL356277.2, AL356473.1, COL12A1, COX7A2, TMEM30A, TMEM30A-DT, FILIP1, HMGB1P39, AL445465.1, U3, MIR4463, AL445465.2, UBE2V1P15, RNU1-34P, RPL26P20, H3P27, RNU6-1338P, SENP6, AL356057.1, RNU6-1016P, RN7SKP163, AL109897.1, MYO6, RNU6-155P, RNA5SP209, IMPG1, Y_RNA, RNU6-248P, RNU6-261P, LINC02540, RNU6-84P, AL591030.1, AL590426.1, AL355612.1, AL365222.1, HTR1B, RPS6P7, MEI4, AL121718.1, AL450327.1, IRAK1BP1, PHIP, AL356776.1, AL356776.2.
- chr6:81,491,439–90,296,908, 145 genes, copy number 8–9 (within-gene range 6–9) (broad region; genes not listed).
- chr6:92,631,066–100,178,192, 68 genes, copy number 7–8 (broad region; genes not listed).
- chr8:131,308,545–145,066,685, 287 genes, copy number 7 (broad region; genes not listed).
- chr10:37,949,573–38,617,344, 23 genes, copy number 8: ZNF25, ZNF25-DT, Y_RNA, ZNF33A, RNU6-795P, AL161931.1, EIF3LP3, FXYD6P2, ZNF37A, AL117339.4, AL117339.3, AL117339.1, CCNYL4, AL133217.1, AL117339.2, HSD17B7P2, SEPTIN7P9, AL133216.2, RNU6-1118P, CICP9, AL133216.1, ABCD1P2, AL133173.2.
- chr11:79,966,805–83,423,516, 46 genes, copy number 7: AP001541.1, AP001284.1, AP006295.1, RNU6-544P, ARL6IP1P3, LINC02720, AP003398.1, AP003398.2, AP003464.1, MTND4LP18, MTND6P25, MIR4300HG, AP002802.2, MIR4300, AP002802.1, AP000793.1, RPS28P7, FAM181B, LINC02734, RBMXP3, PRCP, EIF2S2P6, DDIAS, AP000893.1, AP000893.2, RAB30, AP001767.1, SNORA70E, RAB30-DT, AP001767.2, AP001767.3, COX5BP4, C1DP5, BCAS2P1, PCF11, AP000873.4, AP000873.2, PCF11-AS1, ANKRD42, CKS1BP4, AP000873.3, AP000873.1, CCDC90B, AP000446.1, CYCSP28, AP000446.2.
- chr11:83,643,602–83,725,390, 1 gene, copy number 7 (within-gene range 5–7): DLG2-AS2.
- chr19:21,142,024–21,196,053, 1 gene, copy number 10 (within-gene range 5–10): ZNF431.
- chr19:21,188,598–22,532,485, 59 genes, copy number 10 (within-gene range 2–10): VN1R82P, AC010620.1, AC010620.2, RPL36AP51, AC022432.1, VN1R83P, ZNF708, BNIP3P25, ZNF738, AC010615.3, AC010615.1, ZNF493, AC010615.4, AC010615.2, LINC00664, ZNF429, BNIP3P26, AC123912.1, AC123912.4, AC123912.2, AC123912.6, AC123912.5, AC123912.3, MTDHP3, MTDHP4, VN1R84P, ZNF100, CCNYL6, AC092364.1, BRI3BPP1, ZNF43, BNIP3P27, ZNF208, MTDHP2, AC003973.2, BNIP3P28, AC003973.1, ZNF257, BNIP3P29, ZNF92P2, AC073539.2, PCGF7P, MTDHP5, VN1R85P, ZNF676, BNIP3P30, AC073539.14, AC073539.1, AC073539.3, ZNF729, BNIP3P31, AC011494.1, RPL34P34, ZNF98, AC011516.1, BNIP3P32, AC025811.1, BNIP3P33, ZNF209P.
- chr20:10,637,684–12,381,255, 24 genes, copy number 8–10 (within-gene range 5–10): JAG1, MIR6870, AL050403.2, LINC01752, AL135937.1, AL050403.1, FAT1P1, LINC02871, AL158042.1, AL049649.1, RPS11P1, AL109837.2, AL109837.3, AL109837.1, PGAM3P, AL161938.1, LINC00687, RN7SKP111, AL080274.1, BTBD3, AL035448.1, AL109838.1, AL136460.1, PA2G4P2.

Autosomal genes at a single copy (total copy number 1): 3,007. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
